Somatic mutation profile of tumor specimen TCGA-G3-A7M6-01A (aliquot TCGA-G3-A7M6-01A-11D-A33Q-10) from TCGA case TCGA-G3-A7M6, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage I; Tumor grade: G3; Age at diagnosis: 60.8 years (22,205 days).
Specimen TCGA-G3-A7M6-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 01818f2e-e501-4810-8671-2e3c1d41a6b6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-G3-A7M6-10A (Blood Derived Normal), aliquot TCGA-G3-A7M6-10A-01D-A33Q-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/860d6663-061f-474d-9a88-8c1dd6331975

The open-access MAF lists 104 somatic variants for this specimen: 78 protein-altering or splice-affecting, 22 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 66, Silent 22, Nonsense Mutation 4, Splice Site 4, Intron 3, Frame Shift Del 2, Frame Shift Ins 2, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.644G>A p.S215N | Missense Mutation (SNP) | VAF 28/49 reads (57%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs587782177, COSV52679681, COSV52686793, COSV52700292, COSV52891297; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- AATK | c.3018G>C p.E1006D (on ENST00000326724 / NM_001080395.3; = p.E903D on NM_004920.2) | Missense Mutation (SNP) | VAF 18/63 reads (29%) | SIFT tolerated (0.16); PolyPhen benign (0.045); catalogued as COSV58371305; called by muse, mutect2, varscan2
- ADAM18 | c.1216T>A p.C406S | Missense Mutation (SNP) | VAF 32/61 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55852211; called by muse, mutect2, varscan2
- AGPAT1 | c.478T>C p.S160P | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.435); catalogued as COSV61248418; called by muse, mutect2, varscan2
- ANAPC1 | c.4618C>T p.R1540C | Missense Mutation (SNP) | VAF 101/288 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV61978361; called by muse, mutect2, varscan2
- ANKRD36B | c.2074G>C p.G692R | Missense Mutation (SNP) | VAF 36/166 reads (22%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as COSV51535644; called by muse, varscan2
- ANO9 | c.947C>T p.P316L | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT tolerated (0.52); PolyPhen probably damaging (0.924); catalogued as COSV60450920; called by muse, mutect2, varscan2
- ARFGEF3 | c.5861G>C p.G1954A | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT tolerated (0.2); PolyPhen benign (0.192); catalogued as COSV52466461; called by muse, mutect2, varscan2
- ATP2B2 | c.1768A>T p.T590S (on ENST00000352432; = p.T556S on NM_001683.5) | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as COSV59504468; called by muse, mutect2, varscan2
- C1QC | c.118G>A p.G40S | Missense Mutation (SNP) | VAF 37/97 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs762500174, COSV65889965; called by muse, mutect2
- CAPN11 | c.316A>G p.N106D | Missense Mutation (SNP) | VAF 37/112 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as COSV67238895; called by muse, mutect2, varscan2
- CBX4 | c.690dup p.N231Qfs*81 | Frame Shift Ins (INS) | VAF 17/89 reads (19%) | catalogued as rs772839792; called by mutect2, varscan2
- CD80 | c.232T>A p.S78T | Missense Mutation (SNP) | VAF 33/90 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.397); catalogued as COSV51803044; called by muse, mutect2, varscan2
- CNTLN | c.1788G>T p.K596N | Missense Mutation (SNP) | VAF 43/132 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.167); catalogued as COSV52090691; called by muse, mutect2, varscan2
- COL8A2 | c.853G>A p.A285T | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT tolerated (0.57); PolyPhen benign (0.028); catalogued as rs779407262, COSV57442910; called by muse, mutect2, varscan2
- CPXCR1 | c.539G>A p.C180Y | Missense Mutation (SNP) | VAF 51/134 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.042); catalogued as COSV52163999; called by muse, mutect2, varscan2
- CRYBG1 | c.2050T>C p.F684L | Missense Mutation (SNP) | VAF 34/95 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64813787; called by muse, mutect2, varscan2
- CSMD2 | c.1412A>G p.Q471R | Missense Mutation (SNP) | VAF 34/101 reads (34%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.828); catalogued as COSV53944290; called by muse, mutect2, varscan2
- CWH43 | c.879T>A p.F293L | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.84); catalogued as COSV56942273; called by muse, mutect2, varscan2
- DLC1 | c.2273C>T p.P758L (on ENST00000276297 / NM_001348081.2; = p.P321L on NM_006094.5) | Missense Mutation (SNP) | VAF 5/9 reads (56%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.997); catalogued as COSV52319801; called by muse, mutect2
- DOK4 | c.261C>G p.D87E | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.498); catalogued as COSV54673927; called by muse, mutect2
- DSP | c.2645A>G p.E882G | Missense Mutation (SNP) | VAF 29/81 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as COSV65794533; called by muse, mutect2, varscan2
- DST | c.10123A>G p.K3375E | Missense Mutation (SNP) | VAF 15/56 reads (27%) | SIFT tolerated (0.22); PolyPhen benign (0.015); catalogued as COSV55032111; called by muse, mutect2, varscan2
- EBF1 | c.1607G>A p.S536N | Missense Mutation (SNP) | VAF 12/25 reads (48%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.005); catalogued as COSV58189527; called by muse, mutect2, varscan2
- EMILIN2 | c.350A>G p.D117G | Missense Mutation (SNP) | VAF 20/54 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.812); catalogued as rs773279293, COSV54426178; called by muse, mutect2, varscan2
- EPHA8 | c.1301C>T p.T434I | Missense Mutation (SNP) | VAF 26/90 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.044); catalogued as COSV51284161; called by muse, mutect2, varscan2
- FSTL5 | c.1336G>T p.E446* | Nonsense Mutation (SNP) | VAF 96/289 reads (33%) | catalogued as COSV60190161, COSV60217403; called by muse, mutect2, varscan2
- FZD10 | c.908G>A p.G303E | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57475018; called by muse, mutect2, varscan2
- GEMIN8 | c.473-2A>T p.X158_splice | Splice Site (SNP) | VAF 24/77 reads (31%) | catalogued as COSV60551224; called by muse, mutect2, varscan2
- GLUL | c.973A>G p.I325V | Missense Mutation (SNP) | VAF 38/88 reads (43%) | SIFT tolerated (0.18); PolyPhen benign (0.306); catalogued as COSV59383040; called by muse, mutect2, varscan2
- GRID1 | c.2909C>A p.S970* | Nonsense Mutation (SNP) | VAF 17/79 reads (22%) | catalogued as COSV60015605, COSV60044886; called by muse, mutect2, varscan2
- HNRNPC | c.545C>T p.S182F (on ENST00000420743; = p.S169F on NM_004500.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 25/61 reads (41%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.901); catalogued as COSV60145744, COSV60146580; called by muse, mutect2, varscan2
- HOXA5 | c.173G>A p.R58H | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.005); catalogued as COSV56074397; called by muse, mutect2, varscan2
- HTR2C | c.683C>G p.T228R | Missense Mutation (SNP) | VAF 41/111 reads (37%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.993); catalogued as COSV52201275, COSV52220450; called by muse, mutect2, varscan2
- JARID2 | c.586A>C p.K196Q | Missense Mutation (SNP) | VAF 28/79 reads (35%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.715); catalogued as COSV59195049; called by muse, mutect2, varscan2
- JPH1 | c.917G>C p.G306A | Missense Mutation (SNP) | VAF 30/163 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60610882; called by muse, mutect2, varscan2
- KCNJ14 | c.334G>A p.A112T | Missense Mutation (SNP) | VAF 23/38 reads (61%) | SIFT deleterious (0); PolyPhen possibly damaging (0.872); catalogued as COSV60738637; called by muse, mutect2, varscan2
- LIMK2 | c.1570G>C p.D524H | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59183788; called by muse, mutect2, varscan2
- MAGED1 | c.991G>A p.A331T | Missense Mutation (SNP) | VAF 45/106 reads (42%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.056); catalogued as rs782639348, COSV58515319, COSV58516284; called by muse, mutect2, varscan2
- MECOM | c.1702C>G p.P568A (on ENST00000468789 / NM_001105078.4; = p.P756A on NM_004991.4) | Missense Mutation (SNP) | VAF 22/60 reads (37%) | SIFT tolerated (0.17); PolyPhen benign (0.006); catalogued as rs1287450378, COSV52971051; called by muse, mutect2, varscan2
- MIA3 | c.1779C>G p.D593E | Missense Mutation (SNP) | VAF 23/126 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.015); catalogued as COSV60516172; called by muse, mutect2, varscan2
- MYO5C | c.3116A>G p.E1039G | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.754); catalogued as COSV55910476; called by muse, mutect2, varscan2
- NPAS3 | c.170G>T p.R57L (on ENST00000356141 / NM_001164749.2; = p.R27L on NM_022123.3) | Missense Mutation (SNP) | VAF 24/87 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV58101797; called by muse, mutect2, varscan2
- OR10X1 | c.622A>G p.S208G | Missense Mutation (SNP) | VAF 54/259 reads (21%) | SIFT tolerated (0.05); PolyPhen benign (0.017); catalogued as rs759921821, COSV63767789; called by muse, mutect2, varscan2
- OR2M7 | c.455G>C p.G152A | Missense Mutation (SNP) | VAF 18/125 reads (14%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.998); catalogued as COSV58740165, COSV99049575; called by muse, mutect2, varscan2
- OR5B12 | c.601G>T p.V201L | Missense Mutation (SNP) | VAF 42/90 reads (47%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.111); catalogued as COSV100222519; called by muse, mutect2, varscan2
- OR5D18 | c.728C>T p.A243V | Missense Mutation (SNP) | VAF 19/68 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.658); catalogued as COSV61738193; called by muse, mutect2, varscan2
- OTX2 | c.844T>A p.S282T (on ENST00000408990 / NM_172337.3; = p.S290T on NM_021728.4) | Missense Mutation (SNP) | VAF 32/70 reads (46%) | SIFT deleterious (0.04); PolyPhen benign (0.005); catalogued as COSV59767100; called by muse, mutect2, varscan2
- PDK3 | c.248+1G>C p.X83_splice | Splice Site (SNP) | VAF 23/73 reads (32%) | catalogued as COSV64794058; called by muse, mutect2, varscan2
- PRPF38B | c.955C>G p.R319G | Missense Mutation (SNP) | VAF 49/226 reads (22%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.993); catalogued as COSV64223469, COSV64224334; called by muse, mutect2, varscan2
- PSD4 | c.1655C>T p.S552F | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT tolerated (0.86); PolyPhen benign (0); catalogued as COSV55528957; called by muse, mutect2, varscan2
- RYR2 | c.10255T>G p.F3419V | Missense Mutation (SNP) | VAF 18/204 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV63704156; called by muse, mutect2
- SERPINB6 | c.487G>A p.G163S (on ENST00000612421 / NM_001271823.2; = p.G144S on NM_004568.6) | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.882); catalogued as COSV59566007, COSV59566835; called by muse, mutect2, varscan2
- SLC10A3 | c.1325C>A p.A442D | Missense Mutation (SNP) | VAF 36/120 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54837020; called by muse, mutect2, varscan2
- SLC24A3 | c.423+1G>C p.X141_splice | Splice Site (SNP) | VAF 54/99 reads (55%) | catalogued as COSV60127742; called by muse, mutect2, varscan2
- SLC29A4 | c.462C>A p.D154E | Missense Mutation (SNP) | VAF 23/52 reads (44%) | SIFT tolerated (0.67); PolyPhen benign (0.006); catalogued as COSV51876113; called by muse, mutect2, varscan2
- SLC30A6 | c.45T>A p.F15L | Missense Mutation (SNP) | VAF 31/84 reads (37%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as COSV50871927, COSV50873727; called by muse, mutect2, varscan2
- SREBF2 | c.1580G>T p.G527V | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT tolerated (0.22); PolyPhen benign (0.143); catalogued as COSV63332124; called by muse, mutect2, varscan2
- SYNM | c.1068T>G p.N356K | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.944); catalogued as COSV60373397; called by muse, varscan2
- TFE3 | c.866G>A p.G289E | Missense Mutation (SNP) | VAF 43/122 reads (35%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.966); catalogued as COSV59948639; called by muse, mutect2, varscan2
- TIGD2 | c.1525C>T p.L509F | Missense Mutation (SNP) | VAF 33/76 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as COSV57648507; called by muse, mutect2, varscan2
- TLR8 | c.230A>G p.H77R (on ENST00000218032 / NM_138636.5; = p.H95R on NM_016610.4) | Missense Mutation (SNP) | VAF 96/291 reads (33%) | SIFT tolerated (0.63); PolyPhen benign (0.003); catalogued as rs745722261, COSV54319643; called by muse, mutect2, varscan2
- TRPV3 | c.359A>C p.K120T | Missense Mutation (SNP) | VAF 19/25 reads (76%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.518); catalogued as COSV56793921; called by muse, mutect2, varscan2
- TSPEAR | c.1467C>G p.F489L | Missense Mutation (SNP) | VAF 40/116 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as COSV57869939; called by muse, mutect2, varscan2
- UBE3A | c.715A>G p.I239V | Missense Mutation (SNP) | VAF 27/67 reads (40%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV51669229; called by muse, mutect2, varscan2
- UPF3B | c.1302G>C p.K434N (on ENST00000276201 / NM_080632.3; = p.K421N on NM_023010.3) | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV52231061; called by muse, varscan2
- VASN | c.221G>T p.G74V | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.865); catalogued as COSV52032807; called by muse, mutect2, varscan2
- WRN | c.4230G>A p.W1410* | Nonsense Mutation (SNP) | VAF 15/33 reads (45%) | catalogued as COSV53304869; called by muse, mutect2, varscan2
- ZNF107 | c.560C>A p.P187H | Missense Mutation (SNP) | VAF 25/68 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.636); catalogued as COSV61330969, COSV61332029; called by muse, mutect2, varscan2
- ZNF615 | c.9G>C p.Q3H | Missense Mutation (SNP) | VAF 10/63 reads (16%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.496); catalogued as rs1220092583, COSV65034568; called by muse, mutect2, varscan2
- ZNF678 | c.1363C>A p.H455N | Missense Mutation (SNP) | VAF 16/78 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59386116; called by muse, mutect2, varscan2
- ZSWIM1 | c.1004C>T p.T335I | Missense Mutation (SNP) | VAF 47/90 reads (52%) | SIFT tolerated (0.28); PolyPhen benign (0.044); catalogued as COSV54850119; called by muse, mutect2, varscan2
- DSG2 | c.1879+2dup p.X627_splice | Splice Site (INS) | VAF 5/15 reads (33%) | called by mutect2, varscan2
- GCN1 | c.5820dup p.K1941* | Frame Shift Ins (INS) | VAF 31/90 reads (34%) | called by mutect2, pindel, varscan2
- HIPK3 | c.3176_3207del p.Q1059Rfs*15 | Frame Shift Del (DEL) | VAF 12/72 reads (17%) | called by mutect2, pindel
- MANEAL | c.1149C>G p.Y383* (on ENST00000373045 / NM_001113482.1; = p.Y161* on NM_152496.2) | Nonsense Mutation (SNP) | VAF 5/87 reads (6%) | called by muse, mutect2
- PLXNA2 | c.3400del p.D1134Tfs*31 | Frame Shift Del (DEL) | VAF 119/192 reads (62%) | called by mutect2, pindel, varscan2
- ZCCHC14 | c.7T>C p.S3P (on ENST00000268616; = p.S140P on NM_015144.3) | Missense Mutation (SNP) | VAF 3/42 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.278); called by muse, mutect2
- ACAT2 | c.738C>T p.V246= | Silent (SNP) | VAF 14/58 reads (24%) | catalogued as COSV58460069; called by muse, mutect2, varscan2
- AHRR | c.786G>A p.P262= | Silent (SNP) | VAF 18/121 reads (15%) | catalogued as rs769858803, COSV57086932; called by muse, mutect2, varscan2
- AL645922.1 | c.2076C>T p.H692= | Silent (SNP) | VAF 14/33 reads (42%) | catalogued as COSV54961969; called by muse, mutect2, varscan2
- AP3B1 | c.3162A>G p.S1054= | Silent (SNP) | VAF 17/42 reads (40%) | catalogued as rs772549509, COSV54889703; called by muse, mutect2, varscan2
- BTK | c.1638C>G p.V546= | Silent (SNP) | VAF 16/55 reads (29%) | catalogued as COSV58122663; called by muse, mutect2, varscan2
- CCDC171 | c.2850A>G p.V950= | Silent (SNP) | VAF 26/59 reads (44%) | catalogued as COSV52648952; called by muse, mutect2, varscan2
- CCDC185 | c.1770T>C p.P590= | Silent (SNP) | VAF 50/212 reads (24%) | catalogued as COSV64821566; called by muse, mutect2, varscan2
- DDR1 | c.1314C>A p.L438= | Silent (SNP) | VAF 6/22 reads (27%) | catalogued as COSV100241457, COSV61323667; called by muse, mutect2, varscan2
- DNAJC5B | c.387G>T p.L129= | Silent (SNP) | VAF 24/104 reads (23%) | catalogued as COSV52539082; called by muse, mutect2, varscan2
- EPS8L2 | c.456C>T p.F152= | Silent (SNP) | VAF 3/24 reads (13%) | called by muse, mutect2
- GRIK3 | c.2337C>A p.I779= | Silent (SNP) | VAF 5/30 reads (17%) | catalogued as COSV66144481; called by muse, mutect2, varscan2
- HKDC1 | c.2466C>T p.C822= | Silent (SNP) | VAF 32/67 reads (48%) | catalogued as rs373165480, COSV63578634; called by muse, mutect2, varscan2
- MGA | c.603G>A p.L201= | Silent (SNP) | VAF 22/86 reads (26%) | catalogued as rs779780277, COSV54960294; called by muse, mutect2, varscan2
- MST1R | c.2823C>T p.I941= | Silent (SNP) | VAF 12/42 reads (29%) | catalogued as rs201143544, COSV56572204; called by muse, mutect2, varscan2
- OR5B12 | c.600G>T p.V200= | Silent (SNP) | VAF 41/91 reads (45%) | catalogued as rs760625735, COSV100222520; called by muse, mutect2, varscan2
- PCDHB6 | c.924G>A p.E308= | Silent (SNP) | VAF 7/44 reads (16%) | catalogued as rs782250198, COSV50714564; called by muse, mutect2, varscan2
- RMC1 | c.1509A>G p.E503= | Silent (SNP) | VAF 34/87 reads (39%) | catalogued as COSV52573651; called by muse, mutect2, varscan2
- SYT9 | c.109C>T p.L37= | Silent (SNP) | VAF 22/53 reads (42%) | catalogued as COSV59622974; called by muse, mutect2, varscan2
- TRPM7 | c.4821C>T p.L1607= | Silent (SNP) | VAF 5/68 reads (7%) | catalogued as rs1303706652, COSV100540174; called by muse, mutect2
- VWF | c.5202G>A p.Q1734= | Silent (SNP) | VAF 26/105 reads (25%) | catalogued as rs1241259684, COSV54629889; called by muse, mutect2, varscan2
- XCL2 | c.192T>C p.R64= | Silent (SNP) | VAF 20/158 reads (13%) | catalogued as COSV63194709; called by muse, mutect2, varscan2
- ZNF43 | c.166C>T p.L56= | Silent (SNP) | VAF 33/50 reads (66%) | catalogued as COSV61685235; called by muse, mutect2, varscan2
- ACSM3 | c.1326+191_1326+209del | Intron (DEL) | VAF 67/298 reads (22%) | called by mutect2, pindel, varscan2
- CASP10 | c.1415+8079G>C | Intron (SNP) | VAF 51/154 reads (33%) | catalogued as COSV53779939; called by muse, mutect2, varscan2
- CST7 | c.-18G>T | 5'UTR (SNP) | VAF 28/100 reads (28%) | catalogued as COSV100962010; called by muse, mutect2, varscan2
- TTN | c.10360+2846T>A | Intron (SNP) | VAF 31/82 reads (38%) | catalogued as COSV60245915; called by muse, mutect2, varscan2
